Surgical pathology report (de-identified scan), TCGA case TCGA-61-1740, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1740-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: ILEUM AND DISTAL CECUM, EXCISION –

- A. METASTATIC POORLY DIFFERENTIATED SEROUS CARCINOMA INVOLVING FULL THICKNESS OF BOWEL WALL, EXTENDING TO THE MUCOSAL SURFACE AND SHOWING DIFFUSE LYMPHOVASCULAR INVASION.
- B. SURGICAL MARGINS NEGATIVE.
- C. SIX MESENTERIC LYMPH NODES, POSITIVE FOR TUMOR (6/6).
- D. VERMIFORM APPENDIX WITH FIBROUS OBLITERATION AND WITH METASTATIC POORLY DIFFERENTIATED SEROUS CARCINOMA INFILTRATING SEROSA.

PART 2: SEGMENT OF ILEUM, EXCISION – NEGATIVE FOR TUMOR.

PART 3: UTERUS WITH BOTH ADNEXA (280 GRAMS), TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY –

- A. RIGHT OVARY WITH POORLY DIFFERENTIATED SEROUS CARCINOMA WITH EXTENSIVE NECROSIS AND LYMPHOVASCULAR INVASION (8.0 CM).
- B. CHRONIC CERVICITIS, SQUAMOUS METAPLASIA AND NABOTHIAN CYSTS.
- C. INACTIVE ENDOMETRIUM.
- D. MYOMETRIUM AND SEROSA WITH NODULES OF POORLY DIFFERENTIATED SEROUS CARCINOMA AND WITH DIFFUSE LYMPHOVASCULAR INVASION.
- E. LEIOMYOMAS WITH HYALINE DEGENERATION AND CALCIFICATIONS, UP TO 4.5 CM.
- F. LEFT OVARY, NEGATIVE FOR TUMOR, WITH EPITHELIAL INCLUSIONS AND SURFACE ADHESIONS.
- G. LEFT FALLOPIAN TUBE WITH POORLY DIFFERENTIATED SEROUS CARCINOMA IN THE PERITUBAL TISSUE.
- H. HYDROSALPINX, RIGHT.

PART 4: TUMOR, EXCISION –

- A. POORLY DIFFERENTIATED SEROUS CARCINOMA.
- B. SEGMENT OF COLONIC MUCOSA, UNREMARKABLE.

PART 5: DIAPHRAGMATIC NODULE, EXCISION – POORLY DIFFERENTIATED SEROUS CARCINOMA.

PART 6: OMENTUM, OMENTECTOMY – POORLY DIFFERENTIATED SEROUS CARCINOMA.

PART 7: CUL-DE-SAC TUMOR, EXCISION – POORLY DIFFERENTIATED SEROUS CARCINOMA.

PART 8: COLONIC TUMOR, EXCISION – POORLY DIFFERENTIATED SEROUS CARCINOMA.

Source: NCI Genomic Data Commons file 90ecc83d-9ab9-45d3-aae9-0eeb3630f3b0 (TCGA-61-1740.B87690BA-0CD2-458E-938F-553CD5AB6D84.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).